Somatic mutation profile of tumor specimen TCGA-AN-A0FN-01A (aliquot TCGA-AN-A0FN-01A-11W-A050-09) from TCGA case TCGA-AN-A0FN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.0 years (22,629 days).
Specimen TCGA-AN-A0FN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 499ae223-73cd-41f0-816f-c8e07df77a35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0FN-10A (Blood Derived Normal), aliquot TCGA-AN-A0FN-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d579b4ce-fdec-4225-9538-34e8a964a81b

The open-access MAF lists 37 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 7, Splice Site 1, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY10 | c.3747C>A p.F1249L | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.525); catalogued as COSV100896930; called by muse, mutect2
- ADCY2 | c.2979C>A p.N993K | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100601497, COSV100603231; called by muse, mutect2
- AGO1 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV100940868; called by muse, mutect2
- AKAP11 | c.3527G>A p.S1176N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as rs146952263; called by muse, mutect2, varscan2
- ANK2 | c.8558G>A p.C2853Y | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV100002445; called by muse, mutect2
- ANO4 | c.2674G>A p.E892K (on ENST00000392977 / NM_001286615.2; = p.E857K on NM_178826.4) | Missense Mutation (SNP) | VAF 10/253 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100153135, COSV100153802; called by muse, mutect2
- ARHGAP22 | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs754912116; called by muse, mutect2, varscan2
- BRAF | c.2213A>G p.K738R (on ENST00000288602 / NM_001374244.1; = p.K698R on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV56328531; called by muse, mutect2, varscan2
- C5orf24 | c.388A>G p.K130E | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV100574541; called by muse, mutect2, varscan2
- CFAP221 | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.171); catalogued as rs761656123, COSV99732736; called by muse, mutect2
- COL4A3 | c.3965G>T p.G1322V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101170382; called by muse, mutect2
- CPA2 | c.535C>A p.H179N | Missense Mutation (SNP) | VAF 83/437 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV55981055; called by muse, mutect2, varscan2
- CSMD2 | c.4313C>T p.P1438L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs374808207; called by muse, mutect2, varscan2
- CYP3A7 | c.1140T>A p.D380E | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100312716; called by muse, mutect2, varscan2
- ELN | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV52714243; called by muse, mutect2, varscan2
- ESRP2 | c.863C>A p.A288E (on ENST00000565858 / NM_001365264.1; = p.A278E on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52175428; called by muse, mutect2, varscan2
- FBXO6 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV99336036; called by muse, mutect2
- FGF9 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs753255725, COSV66645469; called by muse, mutect2, varscan2
- ITGB4 | c.2795T>G p.M932R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV52325995, COSV99564264; called by mutect2, varscan2
- LRRN4 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 112/171 reads (65%) | catalogued as COSV66646321; called by muse, mutect2, varscan2
- MYH13 | c.4188dup p.L1397Tfs*74 | Frame Shift Ins (INS) | VAF 17/77 reads (22%) | catalogued as rs760402984; called by mutect2, pindel, varscan2
- PEF1 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101035915; called by muse, mutect2
- POLR3GL | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as rs782502275, COSV65215988; called by muse, mutect2, varscan2
- SIDT2 | c.1728C>A p.F576L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99637954; called by muse, mutect2
- SLCO1C1 | c.691G>C p.V231L | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV56873256, COSV99859348; called by muse, mutect2
- TAF4B | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 16/418 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV52308281; called by muse, mutect2
- XDH | c.2924G>A p.S975N | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs989678725, COSV101052270; called by muse, mutect2
- ZNF791 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.978); catalogued as rs746552226, COSV58482365; called by muse, mutect2, varscan2
- GIGYF2 | c.1807-1G>A p.X603_splice | Splice Site (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- KIAA0232 | c.3888T>G p.L1296= | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as COSV100300823; called by muse, mutect2, varscan2
- KRT31 | c.678C>T p.N226= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as rs760988195, COSV52435427; called by muse, mutect2, varscan2
- PRDM15 | c.33C>T p.F11= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV99520343; called by muse, mutect2
- RALGAPA2 | c.3361C>T p.L1121= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV52507293; called by muse, mutect2, varscan2
- RYR2 | c.14317T>C p.L4773= | Silent (SNP) | VAF 17/196 reads (9%) | catalogued as COSV63697711; called by muse, mutect2
- TIMELESS | c.3015C>T p.N1005= | Silent (SNP) | VAF 29/289 reads (10%) | catalogued as COSV99974092; called by muse, mutect2, varscan2
- TROAP | c.1692T>A p.P564= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99226908; called by muse, mutect2
- A1CF | c.100-6566A>G | Intron (SNP) | VAF 7/90 reads (8%) | catalogued as COSV99256814; called by muse, mutect2
